Somatic mutation profile of tumor specimen HCM-WCMC-0951-C67-01A (aliquot HCM-WCMC-0951-C67-01A-01D-A88H-36) from HCMI case HCM-WCMC-0951-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen HCM-WCMC-0951-C67-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92408d47-feac-4835-9337-3c3477bd0064.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0951-C67-10A (Blood Derived Normal), aliquot HCM-WCMC-0951-C67-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24339f7a-f591-4fc5-bc24-bb6fdc47e630

The open-access MAF lists 107 somatic variants for this specimen: 64 protein-altering or splice-affecting, 39 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 39, Frame Shift Del 3, Splice Site 2, Nonsense Mutation 2, 3'UTR 2, 5'Flank 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAT1 | c.1825C>T p.R609W | Missense Mutation (SNP) | VAF 166/506 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886039312; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2
- NF1 | c.6705-1G>C p.X2235_splice (on ENST00000358273 / NM_001042492.3; = p.X2214_splice on NM_000267.3) | Splice Site (SNP) | VAF 30/68 reads (44%) | catalogued as rs1060500356, CS000886, COSV62198415; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.3215G>A p.R1072K (on ENST00000506720 / NM_001322402.2; = p.R1004K on NM_015236.6) | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.163); catalogued as COSV72230729; called by muse, mutect2, varscan2
- CASR | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 125/332 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs200838528; called by muse, mutect2, varscan2
- DCAF12L2 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 150/344 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV100758954; called by muse, mutect2, varscan2
- EDRF1 | c.3634C>G p.L1212V (on ENST00000356792 / NM_001202438.2; = p.L1178V on NM_015608.2) | Missense Mutation (SNP) | VAF 142/345 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV61764122; called by muse, mutect2, varscan2
- FAM124A | c.800C>T p.T267M (on ENST00000322475 / NM_001242312.2; = p.T303M on NM_145019.4) | Missense Mutation (SNP) | VAF 25/330 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775058541, COSV54475891; called by muse, mutect2
- FAM171A1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 88/227 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1264049602, COSV100968217; called by muse, mutect2, varscan2
- GPR158 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 97/259 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as rs747693904, COSV66266831; called by muse, mutect2, varscan2
- GRID2IP | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 183/438 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV71849859; called by muse, mutect2, varscan2
- H1-2 | c.55C>G p.P19A | Missense Mutation (SNP) | VAF 92/330 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs200705328; called by muse, mutect2
- IGLV1-40 | c.168G>A p.W56* | Nonsense Mutation (SNP) | VAF 77/226 reads (34%) | catalogued as rs752483277; called by muse, mutect2, varscan2
- KIF26A | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 185/458 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs770115028, COSV100181493; called by muse, mutect2, varscan2
- KLRD1 | c.454T>C p.C152R | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181719638, COSV60273966; called by muse, mutect2, varscan2
- NF1 | c.2498C>G p.S833C | Missense Mutation (SNP) | VAF 86/221 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV62191525; called by muse, mutect2, varscan2
- NTRK3 | c.1523T>A p.I508N | Missense Mutation (SNP) | VAF 108/259 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV58119961; called by muse, mutect2, varscan2
- PCDHB4 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 75/177 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.852); catalogued as rs1554274320, COSV52020114; called by muse, mutect2, varscan2
- PEG3 | c.2936C>A p.A979D | Missense Mutation (SNP) | VAF 87/220 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV99687820; called by muse, mutect2, varscan2
- RHOB | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 185/396 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV55355269, COSV55355916; called by muse, mutect2, varscan2
- SDK2 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 90/231 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.342); catalogued as rs774668096, COSV101167082, COSV66196124; called by muse, varscan2
- SLC22A13 | c.985del p.Q329Sfs*5 | Frame Shift Del (DEL) | VAF 57/229 reads (25%) | catalogued as COSV61292126; called by mutect2, pindel, varscan2
- SLC24A2 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 64/81 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1275622190, COSV53864937; called by muse, mutect2, varscan2
- SLC4A2 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 216/499 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV59658815; called by muse, mutect2, varscan2
- TG | c.6707C>T p.P2236L | Missense Mutation (SNP) | VAF 114/313 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145564745; called by muse, mutect2, varscan2
- TMEM179B | c.80C>G p.A27G | Missense Mutation (SNP) | VAF 148/286 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as rs1248126688; called by muse, mutect2, varscan2
- TMEM259 | c.1014G>C p.Q338H | Missense Mutation (SNP) | VAF 14/355 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.378); catalogued as rs927159027; called by muse, mutect2
- TNRC18 | c.8047G>A p.D2683N | Missense Mutation (SNP) | VAF 224/513 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as rs1306379608; called by muse, varscan2
- WDFY3 | c.6577C>T p.R2193C | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as rs1481597056, COSV55711247; called by muse, mutect2, varscan2
- ZNF180 | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.45); catalogued as COSV55419638, COSV55421868; called by muse, mutect2
- ZNF34 | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 21/265 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs369409033; called by muse, mutect2
- ADCY8 | c.2059C>T p.H687Y | Missense Mutation (SNP) | VAF 95/191 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- ADH1C | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- AGBL3 | c.605A>G p.N202S | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANO1 | c.2529C>A p.F843L | Missense Mutation (SNP) | VAF 27/587 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.123); called by muse, mutect2
- ARHGAP23 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 223/531 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- ASCC2 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2
- CACNA2D3 | c.1927G>C p.E643Q | Missense Mutation (SNP) | VAF 83/181 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CDH6 | c.850G>T p.G284W | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL6A5 | c.959A>G p.Q320R | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- DARS2 | c.266T>G p.L89R | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by mutect2, varscan2
- DYNC1H1 | c.10494C>A p.N3498K | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.113); called by muse, mutect2
- ELF3 | c.1024del p.L342Wfs*105 | Frame Shift Del (DEL) | VAF 110/264 reads (42%) | called by pindel, varscan2
- EPM2AIP1 | c.1259A>G p.N420S | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXW9 | c.169_170del p.A57Rfs*19 | Frame Shift Del (DEL) | VAF 178/470 reads (38%) | called by mutect2, pindel, varscan2
- GSR | c.310A>C p.N104H | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGSF21 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 141/354 reads (40%) | SIFT tolerated (0.82); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KIF3A | c.2051+1G>C p.X684_splice | Splice Site (SNP) | VAF 48/92 reads (52%) | called by muse, mutect2, varscan2
- KLHL24 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LCT | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- MYH10 | c.2572G>C p.D858H | Missense Mutation (SNP) | VAF 83/215 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- NEU3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 138/317 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OSBPL10 | c.1239G>C p.L413F | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PADI3 | c.1856C>T p.S619F | Missense Mutation (SNP) | VAF 15/340 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- PCDHGB4 | c.2156C>T p.P719L | Missense Mutation (SNP) | VAF 92/226 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RIMKLB | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 211/263 reads (80%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- RTL4 | c.112G>C p.A38P | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- SLC25A43 | c.690G>A p.Q230= | Splice Region (SNP) | VAF 64/154 reads (42%) | called by muse, mutect2, varscan2
- SLC35G2 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- THSD7A | c.3820C>T p.Q1274* | Nonsense Mutation (SNP) | VAF 57/175 reads (33%) | called by muse, mutect2, varscan2
- TPTE | c.767G>A p.R256K (on ENST00000618007 / NM_199261.4; = p.R238K on NM_199259.4) | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- TRPC7 | c.269A>G p.H90R | Missense Mutation (SNP) | VAF 176/398 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- XIRP1 | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 15/424 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2
- YAF2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 232/408 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ZNF605 | c.820A>C p.T274P | Missense Mutation (SNP) | VAF 37/295 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ABCB5 | c.2319C>T p.F773= (on ENST00000404938 / NM_001163941.2; = p.F328= on NM_178559.6) | Silent (SNP) | VAF 58/77 reads (75%) | called by muse, mutect2, varscan2
- ACADVL | c.1377G>C p.R459= | Silent (SNP) | VAF 6/143 reads (4%) | called by muse, mutect2
- ACTR3 | c.90C>T p.I30= | Silent (SNP) | VAF 41/121 reads (34%) | called by muse, mutect2, varscan2
- ARHGAP22 | c.1893G>C p.L631= | Silent (SNP) | VAF 56/144 reads (39%) | catalogued as COSV50940192; called by muse, mutect2, varscan2
- CD8A | c.141G>A p.L47= | Silent (SNP) | VAF 184/426 reads (43%) | catalogued as rs1378213693; called by muse, mutect2, varscan2
- CDYL | c.1749G>A p.G583= (on ENST00000328908 / NM_001368125.1; = p.G529= on NM_004824.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 156/305 reads (51%) | called by muse, mutect2, varscan2
- CHRD | c.2037G>A p.P679= | Silent (SNP) | VAF 184/478 reads (38%) | catalogued as rs772599596; called by muse, varscan2
- CREBBP | c.6105G>A p.L2035= | Silent (SNP) | VAF 186/405 reads (46%) | called by muse, mutect2, varscan2
- ELMOD3 | c.387G>A p.R129= | Silent (SNP) | VAF 93/215 reads (43%) | called by muse, mutect2, varscan2
- FAM220A | c.477A>G p.Q159= | Silent (SNP) | VAF 151/308 reads (49%) | catalogued as rs142051673; called by muse, mutect2, varscan2
- GINS4 | c.277T>C p.L93= | Silent (SNP) | VAF 60/156 reads (38%) | called by muse, mutect2, varscan2
- GIPC3 | c.3204A>G p.Q1068= | Silent (SNP) | VAF 57/135 reads (42%) | catalogued as rs768575534; called by muse, mutect2, varscan2
- GRAMD1A | c.414C>T p.F138= | Silent (SNP) | VAF 134/319 reads (42%) | called by muse, mutect2, varscan2
- GRIN2A | c.147C>T p.R49= | Silent (SNP) | VAF 211/489 reads (43%) | catalogued as COSV58032762; called by muse, mutect2, varscan2
- GRIP1 | c.3279A>C p.I1093= (on ENST00000359742 / NM_001379345.1; = p.I1041= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 140/275 reads (51%) | called by muse, mutect2, varscan2
- INSM1 | c.543C>T p.R181= | Silent (SNP) | VAF 114/212 reads (54%) | catalogued as rs1210640403; called by mutect2, varscan2
- ITGAL | c.3000T>C p.Y1000= | Silent (SNP) | VAF 83/195 reads (43%) | called by muse, mutect2, varscan2
- IZUMO3 | c.330C>T p.L110= | Silent (SNP) | VAF 52/77 reads (68%) | catalogued as rs1046084177; called by muse, mutect2, varscan2
- KLK15 | c.534A>G p.T178= | Silent (SNP) | VAF 140/303 reads (46%) | called by muse, mutect2, varscan2
- LGI4 | c.1017G>C p.A339= | Silent (SNP) | VAF 175/419 reads (42%) | called by muse, mutect2, varscan2
- MBLAC1 | c.462C>T p.P154= | Silent (SNP) | VAF 198/448 reads (44%) | called by muse, mutect2, varscan2
- MTMR1 | c.1428C>T p.S476= | Silent (SNP) | VAF 70/184 reads (38%) | called by muse, mutect2, varscan2
- NF1 | c.6447G>A p.L2149= (on ENST00000358273 / NM_001042492.3; = p.L2128= on NM_000267.3) | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as COSV62195524; called by muse, mutect2, varscan2
- NR5A2 | c.1623A>G p.A541= (on ENST00000367362 / NM_205860.3; = p.A495= on NM_003822.5) | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as rs747971102, COSV52653556; called by muse, mutect2
- OR4K1 | c.636G>A p.L212= | Silent (SNP) | VAF 50/336 reads (15%) | catalogued as COSV53460460; called by muse, mutect2, varscan2
- PAQR6 | c.156C>T p.I52= | Silent (SNP) | VAF 86/329 reads (26%) | catalogued as COSV52746328; called by muse, mutect2, varscan2
- PDE4B | c.375T>A p.P125= | Silent (SNP) | VAF 111/274 reads (41%) | called by muse, mutect2, varscan2
- PDPK1 | c.738G>A p.A246= | Silent (SNP) | VAF 69/421 reads (16%) | catalogued as rs960518102; called by muse, mutect2, varscan2
- PLA2R1 | c.3027C>T p.F1009= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as COSV51774834; called by muse, mutect2, varscan2
- PLXND1 | c.2841C>T p.I947= | Silent (SNP) | VAF 67/219 reads (31%) | catalogued as COSV60712910; called by muse, mutect2
- RBMXL2 | c.603G>A p.P201= | Silent (SNP) | VAF 168/288 reads (58%) | catalogued as rs1255327617; called by muse, mutect2, varscan2
- RBP3 | c.525C>T p.G175= | Silent (SNP) | VAF 124/287 reads (43%) | called by muse, mutect2, varscan2
- RYR2 | c.4056C>T p.G1352= | Silent (SNP) | VAF 116/211 reads (55%) | catalogued as rs1487552177; called by muse, mutect2, varscan2
- SLC3A1 | c.1686G>A p.E562= | Silent (SNP) | VAF 84/193 reads (44%) | called by muse, mutect2, varscan2
- STX4 | c.517T>C p.L173= | Silent (SNP) | VAF 76/181 reads (42%) | called by muse, mutect2, varscan2
- SUPT6H | c.4503C>T p.F1501= | Silent (SNP) | VAF 86/220 reads (39%) | called by muse, varscan2
- TEX13D | c.1383G>A p.G461= | Silent (SNP) | VAF 51/157 reads (32%) | catalogued as rs1421996848; called by muse, mutect2, varscan2
- TOP1 | c.1446C>T p.I482= | Silent (SNP) | VAF 51/229 reads (22%) | catalogued as rs147984700; called by muse, mutect2, varscan2
- ZNF721 | c.1428T>C p.F476= (on ENST00000338977; = p.F488= on NM_133474.4) | Silent (SNP) | VAF 70/176 reads (40%) | catalogued as rs1465890661; called by muse, mutect2, varscan2
- CDC25B | c.*921T>A | 3'UTR (SNP) | VAF 117/444 reads (26%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+37510G>A | Intron (SNP) | VAF 125/323 reads (39%) | called by muse, mutect2, varscan2
- TAF1 | c.*308del | 3'UTR (DEL) | VAF 49/144 reads (34%) | called by mutect2, pindel, varscan2
- ZNF37BP | chr10:42555707 C>T | 5'Flank (SNP) | VAF 44/118 reads (37%) | catalogued as rs1168189495; called by muse, mutect2, varscan2
